Somatic mutation profile of tumor specimen TCGA-D3-A3C3-06A (aliquot TCGA-D3-A3C3-06A-12D-A19A-08) from TCGA case TCGA-D3-A3C3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A3C3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0429c264-dc40-4603-8915-9e4b27f86a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3C3-10A (Blood Derived Normal), aliquot TCGA-D3-A3C3-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/649cf1e4-910d-4c0a-aa38-c694b8c2fb13

The open-access MAF lists 299 somatic variants for this specimen: 208 protein-altering or splice-affecting, 86 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 86, Nonsense Mutation 13, Splice Site 4, Splice Region 3, Frame Shift Del 2, RNA 2, In Frame Del 1, Intron 1, 5'UTR 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 201/234 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A5 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1569497022, CM134984, CM148135, COSV100089241, COSV60370853; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as rs770637624, CM148158, COSV61676239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99233404; called by muse, mutect2, varscan2
- ABCC12 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60917876; called by muse, mutect2, varscan2
- ACOX3 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs866010696, COSV62713143; called by muse, mutect2, varscan2
- ADAM18 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55852001; called by muse, mutect2, varscan2
- ADAMTS17 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567652287, COSV51492591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS5 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs777534375, COSV53178410; called by muse, mutect2
- ADAMTSL3 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs892864576, COSV54467237; called by muse, mutect2, varscan2
- AFAP1L1 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV57047534; called by muse, mutect2, varscan2
- AFM | c.1266G>T p.L422F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56921954; called by muse, mutect2, varscan2
- ALG13 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.157); catalogued as COSV52644476, COSV99321525; called by muse, mutect2, varscan2
- ANK2 | c.7848A>C p.K2616N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); catalogued as COSV52185592; called by muse, mutect2, varscan2
- ANKRD49 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57060709; called by muse, mutect2, varscan2
- ANO10 | c.1846A>G p.K616E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.114); catalogued as COSV52735789; called by muse, mutect2, varscan2
- ARHGAP30 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100920134, COSV63519062; called by muse, mutect2, varscan2
- ARHGAP44 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV52401694; called by muse, mutect2
- ARID1A | c.4201C>T p.Q1401* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV61382155; called by muse, mutect2, varscan2
- ARSI | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60816658; called by muse, mutect2, varscan2
- ARSL | c.1492T>G p.C498G | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66965884; called by muse, mutect2, varscan2
- ASIC4 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV100761915, COSV61733241; called by muse, mutect2, varscan2
- B3GAT3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53881852; called by muse, mutect2, varscan2
- BCOR | c.3238+1G>T p.X1080_splice | Splice Site (SNP) | VAF 21/101 reads (21%) | catalogued as COSV60717236; called by muse, mutect2, varscan2
- BDP1 | c.3773G>T p.G1258V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV62434399; called by muse, mutect2
- BLM | c.1086C>T p.D362= | Splice Region (SNP) | VAF 26/163 reads (16%) | catalogued as rs375632163; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CARMIL3 | c.2417C>T p.P806L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57728190; called by muse, mutect2, varscan2
- CASP8 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV51848261; called by muse, mutect2, varscan2
- CATSPER4 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 80/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58793250; called by muse, mutect2, varscan2
- CCDC116 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1356623525, COSV53042376; called by muse, mutect2, varscan2
- CDH12 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1181837084, COSV66443960; called by muse, mutect2, varscan2
- CEACAM5 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV55751228; called by muse, mutect2
- CENPC | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV56626043; called by muse, mutect2, varscan2
- CHD2 | c.2578-2A>G p.X860_splice | Splice Site (SNP) | VAF 33/83 reads (40%) | catalogued as rs1280650872, COSV67714012; called by muse, mutect2, varscan2
- CIITA | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs1329546376, COSV60861653; called by muse, mutect2, varscan2
- CLDN6 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs559988226, COSV58510653; called by muse, mutect2, varscan2
- CNTD1 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV59311998; called by muse, mutect2, varscan2
- COG5 | c.2060G>A p.R687Q (on ENST00000347053 / NM_001379512.1; = p.R708Q on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs772812050, COSV51747922; called by muse, mutect2, varscan2
- COL9A2 | c.420G>A p.G140= | Splice Region (SNP) | VAF 38/95 reads (40%) | catalogued as COSV65608047; called by muse, mutect2, varscan2
- DBX1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV57055161; called by muse, mutect2, varscan2
- DLEC1 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1465304584, COSV57305827; called by muse, mutect2, varscan2
- DNAH10 | c.11769G>A p.M3923I (on ENST00000409039; = p.M3862I on NM_207437.3) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV69000423; called by muse, mutect2, varscan2
- DNAH3 | c.5300G>A p.W1767* | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | catalogued as rs1410908991, COSV54548322; called by muse, mutect2, varscan2
- DNAH5 | c.4473G>A p.M1491I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV54208385; called by muse, mutect2, varscan2
- DNAH8 | c.4546C>G p.Q1516E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV59477006; called by muse, mutect2
- DNASE1L1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as rs782184791, COSV50011094; called by muse, mutect2, varscan2
- DNER | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV59175453; called by muse, mutect2, varscan2
- DSCAM | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as COSV68641288; called by muse, mutect2, varscan2
- DSPP | c.923A>C p.E308A | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as COSV56815942; called by muse, mutect2, varscan2
- EIF2AK4 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as rs1303944472, COSV55471892; called by muse, mutect2, varscan2
- EMP3 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV53158719; called by muse, mutect2, varscan2
- EPHA7 | c.2618G>T p.W873L | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65190806; called by muse, mutect2, varscan2
- ERCC2 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs201392911; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- ERICH5 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV59317024; called by muse, mutect2, varscan2
- ERMN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as rs1469712056, COSV101263012, COSV68075619; called by muse, mutect2, varscan2
- FAF1 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV65643461; called by muse, mutect2, varscan2
- FAM237A | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101405589; called by muse, mutect2, varscan2
- FBXO40 | c.6G>A p.G2= | Splice Region (SNP) | VAF 52/121 reads (43%) | catalogued as rs771915884, COSV57527170, COSV57528268; called by muse, mutect2, varscan2
- FBXO40 | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57527179; called by muse, mutect2, varscan2
- FCRL2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.071); catalogued as COSV63838192; called by muse, mutect2, varscan2
- FRMPD3 | c.4211C>T p.S1404L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755437325, COSV52196755; called by muse, mutect2, varscan2
- GAS2 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53412238; called by muse, mutect2, varscan2
- GBP6 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs144008165; called by muse, mutect2, varscan2
- GLP2R | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52329112; called by muse, mutect2, varscan2
- GLS | c.1521G>T p.K507N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV57844963; called by muse, mutect2, varscan2
- GRAMD1A | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs373799637, COSV100526186; called by muse, mutect2, varscan2
- GRIA2 | c.666+1G>A p.X222_splice | Splice Site (SNP) | VAF 14/75 reads (19%) | catalogued as COSV52396280, COSV52404215; called by muse, mutect2, varscan2
- GRIA4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV56917089; called by muse, mutect2, varscan2
- H2AC13 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV62441149; called by muse, mutect2, varscan2
- HEG1 | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761662769, COSV60765278; called by muse, mutect2, varscan2
- HEPH | c.754C>T p.P252S (on ENST00000343002; = p.P306S on NM_138737.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57971231; called by muse, mutect2, varscan2
- HLA-DMB | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs892565761, COSV66870936; called by muse, mutect2, varscan2
- HPSE | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.766); catalogued as COSV60988380, COSV60988481; called by muse, mutect2, varscan2
- HSD17B2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs779171937, COSV52274204; called by muse, mutect2, varscan2
- INSC | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as rs375266524, COSV101089535; called by muse, mutect2, varscan2
- ITGA2B | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234878; called by muse, mutect2, varscan2
- JAKMIP2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1413963940, COSV54614539; called by muse, mutect2, varscan2
- KAT7 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV52016708; called by muse, mutect2, varscan2
- KCNIP4 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752727409, COSV54842738; called by muse, mutect2, varscan2
- KCNJ6 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972394919, COSV55712113; called by muse, mutect2, varscan2
- KCNK5 | c.1129G>C p.V377L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63989345; called by muse, mutect2, varscan2
- KCNN3 | c.1711C>T p.H571Y (on ENST00000618040 / NM_001204087.1; = p.H556Y on NM_002249.6) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55225835; called by muse, mutect2, varscan2
- KDF1 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV57672077; called by muse, mutect2, varscan2
- KMT2A | c.4786C>T p.H1596Y | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63281576; called by muse, mutect2, varscan2
- KRT37 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV56659867; called by muse, mutect2, varscan2
- KRT5 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 66/107 reads (62%) | catalogued as COSV52863196; called by muse, mutect2, varscan2
- LGR6 | c.2765G>A p.G922E (on ENST00000367278 / NM_001017403.1; = p.G870E on NM_021636.3) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV55165536; called by muse, mutect2, varscan2
- LRP1B | c.6343G>A p.D2115N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67269706; called by muse, mutect2, varscan2
- LRP6 | c.3221C>T p.T1074I | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV53793455; called by muse, mutect2, varscan2
- MAGEB2 | c.733T>A p.W245R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66781654; called by muse, mutect2, varscan2
- MAGEB6 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1418126583, COSV66872999; called by muse, mutect2, varscan2
- MAOA | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58645066; called by muse, mutect2, varscan2
- MAP4K3 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55717754, COSV55718869; called by muse, mutect2, varscan2
- MID1IP1 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231136; called by muse, mutect2, varscan2
- MOSPD2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.434); catalogued as rs1439661540, COSV66859647; called by muse, mutect2, varscan2
- MRPS11 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs753261109, COSV57915591; called by muse, mutect2, varscan2
- MSR1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs769087591, COSV100028045, COSV50514195, COSV50531991; called by muse, mutect2, varscan2
- MTM1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM021306, CM133036, COSV60337429; called by muse, mutect2, varscan2
- MUC16 | c.38492C>T p.S12831F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV67490265; called by muse, mutect2, varscan2
- MUC16 | c.23644G>A p.D7882N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV67444238; called by muse, mutect2, varscan2
- MUC17 | c.6689T>A p.M2230K | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60302101; called by muse, varscan2
- MVP | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | catalogued as COSV62423353; called by muse, mutect2, varscan2
- MYCBP2 | c.976G>A p.D326N (on ENST00000357337; = p.D364N on NM_015057.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.702); catalogued as COSV100631066; called by muse, mutect2, varscan2
- MYH9 | c.3859G>A p.G1287R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs781586533, COSV53392564; called by muse, mutect2, varscan2
- MYO7B | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309009843, COSV101268311, COSV67346065; called by muse, mutect2
- NARS2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.164); catalogued as COSV55255312; called by muse, mutect2, varscan2
- NCK2 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51895954; called by muse, mutect2, varscan2
- NCL | c.797_811del p.E267_E271del | In Frame Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs759848849; called by mutect2, varscan2
- NDN | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV59361312; called by muse, mutect2, varscan2
- NPHP1 | c.1511C>T p.P504L (on ENST00000393272 / NM_207181.4; = p.P505L on NM_000272.5) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57211324; called by muse, mutect2, varscan2
- NR5A2 | c.1235A>G p.D412G (on ENST00000367362 / NM_205860.3; = p.D366G on NM_003822.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV52657045; called by muse, mutect2, varscan2
- NRXN3 | c.289C>T p.L97F (on ENST00000557594 / NM_001272020.2; = p.L729F on NM_004796.6) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV55351806; called by muse, mutect2, varscan2
- NUMA1 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV61183820, COSV61190655; called by muse, mutect2, varscan2
- OCIAD2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs764690777, COSV56717670; called by muse, mutect2, varscan2
- OPRPN | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.041); catalogued as COSV68192627; called by muse, mutect2, varscan2
- OR10J1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs748637321, COSV71129549; called by muse, mutect2, varscan2
- OR2A5 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 147/255 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.286); catalogued as COSV68739093; called by muse, mutect2, varscan2
- OR2F1 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 276/379 reads (73%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV67331919, COSV67332004; called by muse, mutect2, varscan2
- OR2H1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV65811372; called by muse, mutect2, varscan2
- OR4C15 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868092808, COSV58951930; called by muse, mutect2, varscan2
- OR4D10 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV73260193; called by muse, mutect2, varscan2
- OR4D6 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs934833702, COSV55659318; called by muse, mutect2, varscan2
- OR5B21 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV64482233; called by muse, mutect2, varscan2
- OR5D13 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 86/288 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV62333131, COSV62335171; called by muse, mutect2, varscan2
- OR5M1 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73202396; called by muse, mutect2
- OR8H1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100476998, COSV57295762; called by muse, mutect2, varscan2
- PAPLN | c.1986-1G>A p.X662_splice (on ENST00000554301; = p.X635_splice on NM_173462.4) | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV53723002; called by muse, mutect2, varscan2
- PCDHAC1 | c.2462A>C p.Y821S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV53867262; called by muse, mutect2, varscan2
- PCDHB11 | c.2125G>C p.V709L | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); catalogued as COSV61313848, COSV61313955; called by muse, mutect2, varscan2
- PCP4 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV60788848; called by muse, varscan2
- PDILT | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as COSV56702147, COSV56704898; called by muse, mutect2, varscan2
- PDPR | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779270546; called by mutect2, varscan2
- PDXDC1 | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV57911504; called by muse, mutect2, varscan2
- PDZD4 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51250946, COSV51252607; called by muse, mutect2, varscan2
- PLCB4 | c.3291C>G p.I1097M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV53816200; called by muse, mutect2
- PLVAP | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs201354703; called by muse, mutect2, varscan2
- PPEF2 | c.1735A>T p.K579* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV54425907; called by muse, mutect2, varscan2
- PRDM14 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99400361; called by muse, varscan2
- PRR15L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/140 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.986); catalogued as COSV56023732, COSV56024341; called by muse, mutect2, varscan2
- PTPRT | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 177/538 reads (33%) | catalogued as COSV62015328; called by muse, mutect2, varscan2
- RBPJ | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60756240; called by muse, mutect2, varscan2
- RENBP | c.921T>G p.D307E | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64170564; called by muse, mutect2, varscan2
- SCFD1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV61727082; called by muse, mutect2, varscan2
- SCNN1D | c.212G>A p.G71D (on ENST00000338555; = p.G235D on NM_001130413.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57644262; called by muse, mutect2, varscan2
- SDAD1 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV62403729; called by muse, mutect2, varscan2
- SERPINB7 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV60535585; called by muse, mutect2, varscan2
- SGTB | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs1244465969, COSV66818487; called by muse, mutect2, varscan2
- SIGLEC1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV52471671; called by muse, mutect2, varscan2
- SIRPB1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.764); catalogued as rs747900541, COSV53537349, COSV53541567; called by muse, mutect2, varscan2
- SLC16A14 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54617325; called by muse, mutect2, varscan2
- SLC1A1 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV52057674; called by muse, mutect2, varscan2
- SLC22A2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV65268961; called by muse, mutect2, varscan2
- SLC30A8 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 183/452 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs984319167, COSV69970447; called by muse, varscan2
- SLC44A2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1300382285, COSV59838751; called by muse, mutect2, varscan2
- SNX16 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV62034397; called by muse, mutect2, varscan2
- SNX29 | c.2327C>T p.T776I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs763118960, COSV60066694, COSV60069585; called by muse, mutect2, varscan2
- SORL1 | c.5431A>G p.T1811A | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV52761780; called by muse, mutect2, varscan2
- SP140 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as COSV59446076; called by muse, mutect2
- SP140 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59454527; called by muse, mutect2, varscan2
- SPEG | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56678802; called by muse, mutect2, varscan2
- SPOCK1 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as COSV56464580; called by muse, mutect2, varscan2
- SPRED2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62692564; called by muse, mutect2, varscan2
- STAB1 | c.7211G>A p.G2404E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV58742420; called by muse, mutect2
- STAG2 | c.2486T>A p.I829N | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV54371401; called by muse, mutect2, varscan2
- STPG2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs751504664, COSV54818821; called by muse, mutect2, varscan2
- SUGP2 | c.1423C>T p.L475F | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58264638; called by muse, mutect2, varscan2
- TANC2 | c.5081A>T p.K1694I | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV67340827; called by muse, mutect2, varscan2
- TBX20 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV68785618; called by muse, mutect2, varscan2
- TENM1 | c.6523G>A p.D2175N | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64441714; called by muse, mutect2, varscan2
- TGFBR2 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as COSV55459080; called by muse, mutect2, varscan2
- TLR7 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as COSV66125437; called by muse, mutect2, varscan2
- TMEM94 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV58599488; called by muse, mutect2, varscan2
- TOP3A | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58180805; called by muse, mutect2, varscan2
- TPO | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV61110150; called by muse, mutect2
- TPO | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781420871, COSV61100326; called by muse, mutect2, varscan2
- TRANK1 | c.7261G>A p.V2421M | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs924976437, COSV57162816; called by muse, mutect2, varscan2
- TRMT10C | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV59306791, COSV59307091; called by muse, mutect2, varscan2
- TTN | c.92165A>T p.K30722I (on ENST00000591111; = p.K23298I on NM_003319.4) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | PolyPhen probably damaging (0.974); catalogued as COSV60311585; called by muse, mutect2, varscan2
- TTN | c.14611C>A p.Q4871K (on ENST00000591111; = p.Q3944K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | PolyPhen probably damaging (0.979); catalogued as rs886038908, COSV60279386, COSV60311684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUB | c.134C>T p.P45L (on ENST00000299506 / NM_177972.3; = p.P100L on NM_003320.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV55109836; called by muse, mutect2, varscan2
- UBE2O | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV60067353; called by muse, mutect2, varscan2
- UBR5 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55298993; called by muse, mutect2, varscan2
- UGT1A6 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773557629, COSV59397301; called by muse, mutect2, varscan2
- UMODL1 | c.3620A>T p.N1207I (on ENST00000408910 / NM_001004416.2; = p.N1335I on NM_173568.3) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1209424611, COSV68570905; called by muse, varscan2
- UNC93A | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.083); catalogued as rs1245525510, COSV57810717; called by muse, mutect2, varscan2
- USP26 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1315125161, COSV100896695, COSV63708082; called by muse, mutect2, varscan2
- USP40 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs761956910, COSV52484499, COSV99295916; called by muse, mutect2, varscan2
- VNN2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as rs751165081, COSV58472139; called by muse, mutect2, varscan2
- XRCC5 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67537810; called by muse, mutect2, varscan2
- ZDHHC5 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54709054; called by muse, mutect2, varscan2
- ZNF160 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62000625; called by muse, mutect2, varscan2
- ZNF33B | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.272); catalogued as COSV63943318; called by muse, mutect2, varscan2
- ZNF365 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67926472; called by muse, mutect2, varscan2
- ZNF43 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs765802448, COSV100731887, COSV61682737; called by muse, mutect2, varscan2
- ZNF43 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100731888; called by muse, mutect2, varscan2
- ZNF536 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV62833216; called by muse, mutect2, varscan2
- ZNF540 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57107849, COSV57111217; called by muse, mutect2, varscan2
- ZNF578 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101405064, COSV69737487; called by muse, varscan2
- ZNF630 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52098069; called by muse, mutect2, varscan2
- ZSCAN18 | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53736915; called by muse, mutect2
- ACSM2A | c.1100G>A p.G367E (on ENST00000219054; = p.G288E on NM_001308169.2) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); called by muse, mutect2
- BROX | c.781_782del p.L261Ifs*3 | Frame Shift Del (DEL) | VAF 122/366 reads (33%) | called by mutect2, pindel, varscan2
- EXOC4 | c.942del p.T315Qfs*25 | Frame Shift Del (DEL) | VAF 67/111 reads (60%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12L | c.314T>G p.V105G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDPR | c.321A>T p.K107N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PRAMEF19 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ABCD2 | c.1929C>T p.V643= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as rs56388075; called by muse, mutect2, varscan2
- ABCG1 | c.66G>A p.E22= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV59209902; called by muse, mutect2, varscan2
- ACOT11 | c.663G>A p.E221= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs528025715, COSV59351661; called by muse, mutect2, varscan2
- ALDH2 | c.153G>A p.R51= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV55670027; called by muse, mutect2, varscan2
- ARG1 | c.669G>A p.K223= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV51581758; called by muse, mutect2, varscan2
- ASIC2 | c.873C>T p.S291= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV56768245; called by muse, mutect2, varscan2
- ATP1B2 | c.54G>A p.K18= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1286683626, COSV51516591; called by muse, mutect2, varscan2
- ATP2B3 | c.1647C>A p.G549= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54859937; called by muse, mutect2, varscan2
- BRINP2 | c.696G>T p.L232= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV64179877; called by muse, mutect2, varscan2
- C1QTNF1 | c.84C>T p.P28= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV59264101; called by muse, mutect2, varscan2
- CASP3 | c.801C>A p.S267= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV57725765; called by muse, mutect2, varscan2
- CCT3 | c.243C>T p.I81= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs1412722131, COSV55291228; called by muse, mutect2, varscan2
- CKAP5 | c.2403C>T p.L801= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs1321126544, COSV56373520; called by muse, mutect2, varscan2
- CLCN2 | c.2064G>A p.R688= | Silent (SNP) | VAF 82/200 reads (41%) | catalogued as COSV55604034; called by muse, mutect2, varscan2
- CNPPD1 | c.372G>C p.L124= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs549300776, COSV55409312; called by muse, mutect2, varscan2
- CROCC | c.660C>T p.I220= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV65014682; called by muse, mutect2
- CTSG | c.354C>T p.V118= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV53536714; called by muse, mutect2, varscan2
- DKK2 | c.417C>T p.I139= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs771637130, COSV53402951, COSV99568553; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.186C>T p.I62= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV61081126; called by muse, mutect2, varscan2
- EPHA4 | c.675C>T p.S225= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV56043259; called by muse, mutect2, varscan2
- F10 | c.1395C>T p.S465= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV65022915; called by muse, mutect2, varscan2
- F8 | c.607C>T p.L203= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV64278118; called by muse, mutect2, varscan2
- FGF7 | c.375A>G p.G125= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV51067417; called by muse, mutect2, varscan2
- FHDC1 | c.1458C>T p.S486= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1181510512, COSV52602728; called by muse, mutect2, varscan2
- GCSAML | c.360T>C p.P120= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV63579391; called by muse, mutect2, varscan2
- GLI2 | c.3450T>A p.P1150= (on ENST00000361492 / NM_001374353.1; = p.P1167= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV58050546; called by muse, mutect2, varscan2
- GMEB2 | c.1350C>T p.D450= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs769649568, COSV56609484; called by muse, mutect2
- GSTCD | c.882C>T p.I294= (on ENST00000360505 / NM_001031720.3; = p.I207= on NM_024751.3) | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV64735400; called by muse, mutect2, varscan2
- HRC | c.1128G>A p.E376= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV53258623; called by muse, mutect2, varscan2
- ITGB1BP2 | c.429C>T p.I143= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV52140016; called by muse, mutect2, varscan2
- KCNK18 | c.711G>A p.Q237= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV57972242; called by muse, mutect2
- KIAA0513 | c.231C>T p.S77= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV50741074; called by muse, mutect2, varscan2
- KIF16B | c.3204A>G p.E1068= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV61713841; called by muse, mutect2, varscan2
- MCOLN1 | c.870C>T p.F290= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs754009842, COSV51175141; called by muse, mutect2, varscan2
- MEFV | c.120C>T p.I40= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as rs1454105754, COSV54822994, COSV54824223; called by muse, mutect2, varscan2
- MFF | c.171G>A p.P57= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs767787568, COSV100449362; called by muse, mutect2, varscan2
- MRM2 | c.486C>T p.F162= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV54249093; called by muse, mutect2, varscan2
- MYO7B | c.4575G>A p.K1525= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1298807191, COSV67346607; called by muse, mutect2
- NBEAL2 | c.7566G>A p.R2522= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs762908007, COSV52762496; called by muse, mutect2, varscan2
- NOXRED1 | c.969C>T p.L323= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs772482722, COSV53630448; called by muse, mutect2, varscan2
- OR10G4 | c.634C>T p.L212= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV57978178; called by muse, mutect2, varscan2
- OR3A3 | c.894C>T p.I298= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV52168495; called by muse, mutect2, varscan2
- OR51B4 | c.567C>T p.I189= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV66517713; called by muse, mutect2, varscan2
- OR5B17 | c.885G>A p.V295= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV62161018; called by muse, mutect2, varscan2
- OTOP2 | c.216G>A p.L72= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV58883560; called by muse, mutect2
- PADI4 | c.186C>T p.S62= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs1259451839, COSV64924990; called by muse, mutect2, varscan2
- PCDHA5 | c.1917C>T p.T639= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV65357157; called by muse, mutect2
- PCDHA8 | c.2103C>T p.I701= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV65330769; called by muse, mutect2, varscan2
- PER1 | c.2082G>A p.R694= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV57921892; called by muse, mutect2, varscan2
- PGLYRP2 | c.813C>T p.A271= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99484176; called by muse, mutect2
- PI4K2B | c.1011T>C p.L337= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV53512904; called by muse, mutect2, varscan2
- PIK3C3 | c.2112T>C p.F704= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV56283948; called by mutect2, varscan2
- PLG | c.1233G>A p.K411= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV51986156; called by muse, mutect2, varscan2
- PLXDC2 | c.834C>T p.V278= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs771311773, COSV65908567; called by muse, mutect2, varscan2
- PRDM14 | c.315C>T p.P105= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs936499705, COSV52575185; called by muse, mutect2, varscan2
- RIBC1 | c.1083C>T p.I361= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV51448788; called by muse, mutect2
- RIMS1 | c.753C>T p.A251= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV53481546; called by muse, mutect2, varscan2
- SEC14L3 | c.594C>T p.F198= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs1260786548, COSV53181304; called by muse, varscan2
- SERPINI1 | c.63C>T p.F21= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV55514465; called by muse, mutect2, varscan2
- SESN2 | c.1305C>T p.T435= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs533860749, COSV53429036; called by muse, mutect2, varscan2
- SGO2 | c.1462C>T p.L488= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV63417709; called by muse, mutect2, varscan2
- SLC5A2 | c.642C>T p.I214= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV57894366; called by muse, mutect2, varscan2
- SPON1 | c.2034G>A p.S678= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs782259883, COSV100116758, COSV59961333; called by muse, mutect2, varscan2
- SPRED2 | c.1011C>A p.I337= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100710284, COSV62693118; called by muse, mutect2, varscan2
- STIL | c.2463C>A p.S821= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV54553284; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2868G>A p.Q956= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV59136078, COSV59137471; called by muse, mutect2, varscan2
- THSD7B | c.1251C>T p.L417= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs766261059, COSV55733008; called by muse, mutect2, varscan2
- TM9SF2 | c.1678C>T p.L560= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV64507460; called by muse, mutect2, varscan2
- TRPV4 | c.411C>T p.A137= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV55683894, COSV99924385; called by muse, mutect2, varscan2
- TTLL6 | c.1362G>A p.R454= (on ENST00000393382 / NM_001130918.3; = p.R147= on NM_173623.3) | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs200684036, COSV64979255; called by muse, mutect2, varscan2
- TTN | c.43857C>T p.L14619= (on ENST00000591111; = p.L7195= on NM_003319.4) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV60311628; called by muse, mutect2, varscan2
- TTN | c.32769G>A p.K10923= (on ENST00000591111; = p.K9996= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV60311666; called by muse, mutect2, varscan2
- TUBA3C | c.702C>T p.I234= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs142245280; called by muse, mutect2, varscan2
- TUBG2 | c.711G>C p.S237= | Silent (SNP) | VAF 47/111 reads (42%) | catalogued as COSV52219483; called by muse, mutect2, varscan2
- USP49 | c.1071C>T p.L357= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV51900826; called by muse, mutect2, varscan2
- VGLL3 | c.393C>T p.P131= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs369382634, COSV67354404; called by muse, mutect2, varscan2
- VWA2 | c.1884C>T p.A628= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV53910845; called by muse, mutect2, varscan2
- VWA5A | c.555C>G p.T185= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV63708223; called by muse, mutect2
- ZBTB18 | c.966C>T p.V322= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV62398295; called by muse, mutect2, varscan2
- ZBTB20 | c.2130G>A p.T710= (on ENST00000474710 / NM_001164342.2; = p.T637= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs368883213; called by muse, mutect2, varscan2
- ZFAT | c.1566G>A p.E522= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs771436764, COSV64745826; called by muse, mutect2, varscan2
- ZFPM2 | c.1752C>T p.F584= | Silent (SNP) | VAF 37/191 reads (19%) | catalogued as COSV65872663; called by muse, mutect2, varscan2
- ZNF195 | c.1059C>T p.P353= (on ENST00000399602 / NM_001130520.3; = p.P281= on NM_007152.5) | Silent (SNP) | VAF 53/160 reads (33%) | catalogued as COSV50007536; called by muse, mutect2, varscan2
- ZNF264 | c.1752C>T p.T584= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV54043566; called by muse, mutect2, varscan2
- ZNF473 | c.1710C>T p.T570= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs546482296, COSV54524951; called by muse, mutect2
- ZNF83 | c.1305G>A p.G435= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV56532029; called by muse, mutect2, varscan2
- C15orf54 | n.563C>T | RNA (SNP) | VAF 51/195 reads (26%) | catalogued as rs765774743; called by muse, mutect2, varscan2
- ERAL1 | chr17:28861615 C>T | 3'Flank (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- SNORD115-9 | n.9G>A | RNA (SNP) | VAF 103/271 reads (38%) | catalogued as rs757240325; called by muse, mutect2, varscan2
- VWF | c.55+263G>A | Intron (SNP) | VAF 60/92 reads (65%) | catalogued as COSV99779626; called by muse, mutect2, varscan2
- ZFHX3 | c.-798C>T | 5'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as COSV73947886, COSV73947948; called by muse, mutect2
